Somatic mutation profile of tumor specimen MMRF_1155_1_BM_CD138pos (aliquot MMRF_1155_1_BM_CD138pos_T1_KBS5U_L05843) from MMRF case MMRF_1155, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,036 days).
Specimen MMRF_1155_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 701f0695-1619-4a87-9903-1aba9c6e989b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1155_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1155_1_PB_Whole_C2_KBS5U_L05768; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/254a2f5c-15f3-472f-b3cb-a09ccb3bcaaa

The open-access MAF lists 140 somatic variants for this specimen: 49 protein-altering or splice-affecting, 22 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 40, Intron 22, Silent 22, 5'UTR 3, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 2, Frame Shift Ins 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as rs984975545, COSV51125252; called by muse, mutect2
- ATP6V1B1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1553419944; called by muse, mutect2, varscan2
- CNTNAP1 | c.1642_1643del p.M548Vfs*2 | Frame Shift Del (DEL) | VAF 66/151 reads (44%) | catalogued as rs1262146130; called by mutect2, pindel, varscan2
- DMC1 | c.858dup p.P287Tfs*31 | Frame Shift Ins (INS) | VAF 42/102 reads (41%) | catalogued as rs1359383682; called by mutect2, pindel, varscan2
- ETFDH | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM110987, COSV57014659; called by muse, mutect2, varscan2
- FGD5 | c.1334del p.G445Efs*18 | Frame Shift Del (DEL) | VAF 33/186 reads (18%) | catalogued as COSV53250036; called by mutect2, pindel, varscan2
- HS3ST3A1 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as rs1013190360; called by muse, mutect2, varscan2
- IGHD6-19 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 68/75 reads (91%) | catalogued as rs547049153; called by muse, mutect2, varscan2
- IGKV1-5 | c.63A>T p.K21N | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs377188226; called by muse, varscan2
- KIAA1217 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs970873382; called by muse, mutect2
- LAMC3 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1489032372; called by muse, mutect2, varscan2
- MAP6 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777211062; called by muse, mutect2, varscan2
- PTPRD | c.4727A>T p.E1576V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61968475; called by muse, mutect2, varscan2
- RELN | c.3987G>A p.M1329I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1562908501, COSV59040768; called by muse, mutect2, varscan2
- SDK1 | c.4676T>C p.I1559T | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs763847417; called by muse, mutect2, varscan2
- SHANK1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53252050; called by muse, mutect2, varscan2
- TRIML1 | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV60193419; called by muse, mutect2, varscan2
- TTYH1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs771847339; called by muse, mutect2, varscan2
- UMOD | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs763212690, COSV56773531; called by muse, mutect2, varscan2
- ZNF462 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 128/220 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52953226; called by muse, mutect2, varscan2
- ABLIM2 | c.676G>C p.A226P | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP13A5 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CACTIN | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CIT | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CTXN3 | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CWH43 | c.1157dup p.R387Qfs*4 | Frame Shift Ins (INS) | VAF 28/57 reads (49%) | called by mutect2, pindel, varscan2
- DOK7 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXOSC10 | c.236G>T p.R79M | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GBA | c.1306T>G p.F436V | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- GNAQ | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM5 | c.2966G>A p.G989E (on ENST00000305447 / NM_001143831.2; = p.G957E on NM_000842.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HUWE1 | c.8006T>C p.V2669A | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- IGKJ5 | chr2:88860559 ATTACTTACGTTTAATCT>CC | Missense Mutation (DEL) | VAF 19/117 reads (16%) | called by pindel, varscan2*
- INTS4 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRP6 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MAGED1 | c.1008_1025del p.A337_V342del | In Frame Del (DEL) | VAF 42/55 reads (76%) | called by mutect2, varscan2
- MAX | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 70/78 reads (90%) | called by muse, mutect2, varscan2
- MMRN1 | c.3541A>C p.I1181L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MRPL10 | c.119T>G p.M40R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NPPB | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 98/176 reads (56%) | called by muse, varscan2
- NTRK3 | c.1985A>G p.Q662R | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PALLD | c.439A>C p.T147P | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP5K1A | c.525C>A p.S175R (on ENST00000368888 / NM_001135638.2; = p.S162R on NM_003557.3) | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PLA2G4D | c.953A>C p.D318A | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PREX2 | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- SH3TC2 | c.2726T>C p.L909P | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC4A2 | c.2182G>C p.G728R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMEM245 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZFYVE16 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AGAP3 | c.873C>T p.G291= (on ENST00000622464; = p.G327= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs544517501; called by muse, mutect2, varscan2
- ALG2 | c.1248A>G p.V416= | Silent (SNP) | VAF 57/201 reads (28%) | called by muse, mutect2, varscan2
- CLEC4G | c.255G>A p.K85= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- CRX | c.726G>T p.V242= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as COSV55758187; called by muse, mutect2, varscan2
- DNAH7 | c.10653C>T p.I3551= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV100415299; called by muse, mutect2, varscan2
- DTX3 | c.711C>T p.T237= | Silent (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- EZH1 | c.837C>T p.G279= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- GATAD2A | c.1596G>T p.R532= | Silent (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- GNE | c.549A>G p.K183= (on ENST00000396594 / NM_001128227.3; = p.K152= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2
- IGHD6-19 | c.15C>T p.G5= | Silent (SNP) | VAF 67/73 reads (92%) | called by muse, mutect2, varscan2
- KAT5 | c.675C>T p.I225= | Silent (SNP) | VAF 76/199 reads (38%) | catalogued as rs778427253; called by muse, mutect2, varscan2
- MDH1B | c.1008A>G p.G336= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.6483T>G p.S2161= | Silent (SNP) | VAF 63/99 reads (64%) | called by muse, mutect2, varscan2
- NPPB | c.108G>A p.S36= | Silent (SNP) | VAF 98/179 reads (55%) | catalogued as rs1039076006, COSV100916106; called by muse, varscan2
- OR4D6 | c.744T>C p.T248= | Silent (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- PCLO | c.1845C>A p.T615= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV61639685; called by muse, mutect2, varscan2
- PEX11G | c.675C>T p.S225= | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- PTBP3 | c.84A>T p.G28= | Silent (SNP) | VAF 67/232 reads (29%) | called by muse, mutect2, varscan2
- RBM15B | c.2655C>T p.I885= | Silent (SNP) | VAF 106/324 reads (33%) | catalogued as rs201500904; called by muse, mutect2, varscan2
- SLC45A1 | c.237C>T p.H79= | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as rs779076880; called by muse, mutect2, varscan2
- STAP2 | c.1095C>T p.G365= (on ENST00000594605 / NM_001013841.2; = p.G411= on NM_017720.3) | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- ZNF618 | c.1938C>T p.S646= (on ENST00000374126 / NM_001318042.2; = p.S553= on NM_133374.2) | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs376683289; called by muse, mutect2, varscan2
- ACTA2 | c.991-156A>G | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- AFAP1 | c.*2469C>T | 3'UTR (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- AR | c.*2261C>T | 3'UTR (SNP) | VAF 13/14 reads (93%) | catalogued as rs1569317253; called by muse, mutect2, varscan2
- ARID5B | c.*1071C>G | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- ATP10D | c.*816C>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- C10orf90 | c.*822T>C | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- C1QTNF12 | c.178-55C>T | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- C1orf158 | c.*1461T>A | 3'UTR (SNP) | VAF 41/113 reads (36%) | called by muse, mutect2, varscan2
- C5orf38 | c.*348T>C | 3'UTR (SNP) | VAF 86/187 reads (46%) | called by muse, mutect2, varscan2
- CARNMT1 | c.*125A>G | 3'UTR (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- CHFR | chr12:132840334 G>C | 3'Flank (SNP) | VAF 5/13 reads (38%) | catalogued as rs542673371; called by muse, varscan2
- CLSTN1 | c.*528T>G | 3'UTR (SNP) | VAF 52/93 reads (56%) | called by muse, mutect2, varscan2
- CPE | c.*115T>C | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- CREB1 | c.*2172A>C | 3'UTR (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- DLGAP1 | c.957+4828A>G | Intron (SNP) | VAF 97/190 reads (51%) | called by muse, mutect2, varscan2
- DNMT3A | c.1014+72G>C | Intron (SNP) | VAF 19/80 reads (24%) | catalogued as COSV104391749, COSV53038292; called by mutect2, varscan2
- DPP4 | c.7-84T>G | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- DUOX2 | c.3184+61G>C | Intron (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- EIF3J | c.*308G>C | 3'UTR (SNP) | VAF 50/123 reads (41%) | catalogued as COSV56000340; called by muse, mutect2, varscan2
- ELOF1 | c.*62G>A | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- ENAH | c.*1847del | 3'UTR (DEL) | VAF 30/72 reads (42%) | catalogued as rs898565355; called by mutect2, varscan2
- FIGN | c.*1303del | 3'UTR (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- GAB1 | chr4:143474078 C>G | 3'Flank (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- GABRB3 | c.241-7531G>T | Intron (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- GABRG1 | c.*5089A>G | 3'UTR (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- GANAB | c.560+13G>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs1224298699; called by muse, mutect2
- GLRA3 | c.*3685T>C | 3'UTR (SNP) | VAF 48/71 reads (68%) | called by muse, mutect2, varscan2
- GRM1 | c.*976C>T | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- H3C11 | c.*6C>G | 3'UTR (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- HSPA5 | c.-140T>C | 5'UTR (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- IFIT5 | c.*2270C>A | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- IGSF11 | c.*552G>T | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- KCNH6 | c.1501+61T>C | Intron (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- LARP4B | c.*368T>C | 3'UTR (SNP) | VAF 23/54 reads (43%) | catalogued as rs956494097, COSV60219726; called by muse, varscan2
- LCE1A | c.*167T>G | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- LSM1 | chr8:38176561 G>A | 5'Flank (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- MAP4 | c.292+3950T>A | Intron (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- MED19 | c.*199T>G | 3'UTR (SNP) | VAF 56/96 reads (58%) | called by muse, mutect2, varscan2
- MOG | c.730+78G>A | Intron (SNP) | VAF 67/122 reads (55%) | catalogued as rs774294135; called by muse, mutect2, varscan2
- NFAT5 | c.-95C>A | 5'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- NFKBID | c.153-34G>A | Intron (SNP) | VAF 22/117 reads (19%) | catalogued as rs752418290; called by muse, mutect2, varscan2
- NRDC | chr1:51878894 del GACT | 5'Flank (DEL) | VAF 84/148 reads (57%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.282+15A>T | Intron (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- PARVA | c.*1327C>A | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- PDGFRL | c.*45T>C | 3'UTR (SNP) | VAF 78/163 reads (48%) | called by muse, mutect2, varscan2
- PLIN5 | c.*50C>A | 3'UTR (SNP) | VAF 29/83 reads (35%) | catalogued as rs779628821; called by muse, mutect2, varscan2
- PPP1CC | c.883-247C>A | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- PRPF18 | c.66+4694G>T | Intron (SNP) | VAF 58/136 reads (43%) | called by muse, mutect2
- PTGES3L-AARSD1 | c.724+36G>A | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2
- RAB40B | c.*184G>T | 3'UTR (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*2128C>T | 3'UTR (SNP) | VAF 47/135 reads (35%) | called by muse, mutect2, varscan2
- RNF24 | c.*1032A>G | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as rs566643183; called by muse, mutect2, varscan2
- SLC25A31 | c.*418A>C | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- SLC37A1 | c.-120C>A | 5'UTR (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- SLC52A2 | c.1002-38G>T | Intron (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- SRBD1 | c.*540G>T | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- SRPK1 | c.1691-24T>C | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- STAC | c.*1383T>A | 3'UTR (SNP) | VAF 16/61 reads (26%) | catalogued as COSV56211634; called by muse, mutect2, varscan2
- STIMATE | c.*2488_*2507del | 3'UTR (DEL) | VAF 6/85 reads (7%) | catalogued as COSV104422124; called by mutect2, pindel, varscan2
- TAGLN2 | c.-29+859T>C | Intron (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- TBC1D12 | c.*1361T>G | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- THBS3 | c.2074+24G>A | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as rs746326628; called by muse, mutect2, varscan2
- TRPA1 | c.*335C>T | 3'UTR (SNP) | VAF 49/85 reads (58%) | called by muse, mutect2, varscan2
- TSPAN31 | c.558+9C>G | Intron (SNP) | VAF 143/151 reads (95%) | called by muse, mutect2, varscan2
- TSPAN33 | c.*935C>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- TXLNG | c.*2149G>C | 3'UTR (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- UTRN | c.7479+6221T>C | Intron (SNP) | VAF 65/118 reads (55%) | called by muse, mutect2, varscan2
- VILL | c.*26_*27del | 3'UTR (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- WDR82 | c.*2147G>C | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
